Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3898, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3898-01A (Primary Tumor).

Diagnosis/ Diagnoses

Resected colon and rectal sample with tumor-free resection margins and including an ulcerated, moderately differentiated (G2) adenocarcinoma with infiltration of the perimuscular fatty tissue and without local lymph node metastases (pT3 pN0 0/21 L0 V0 R0).

Source: NCI Genomic Data Commons file 8d2182a4-834d-4721-a835-db06fff0769f (TCGA-AG-3898.3A8602A7-D073-4ACB-BF5C-427ABA521CB7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).